Surgical pathology report (de-identified scan), TCGA case TCGA-49-6742, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-6742-01A (Primary Tumor).

[page 1 of 2]
fficial report.

=====

SURG PATH REPORT

COLLECTION DATE/TIME: [REDACTED]

. 1st Specimen collected on [REDACTED]

[REDACTED] Accessioned on [REDACTED]

. FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1. L10 LYMPH NODE (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR (0/1).

. 2. LEFT UPPER LOBE LUNG (LOBECTOMY):

. SPECIMEN TYPE:

Lobectomy.

. TUMOR SITE:

Left, Upper lobe.

. HISTOLOGIC TYPE:

Adenocarcinoma with mucinous features.

. TUMOR SIZE:

Greatest dimension 5.0cm.

. HISTOLOGIC GRADE:

G2: Moderately differentiated.

. LYMPH NODES:

Metastatic carcinoma in 1 of 11 lymph nodes (Parts 1-5).

. DIRECT EXTENSION OF TUMOR:

Invades visceral pleura (Movatt stain)

. EXTENT OF INVASION

PRIMARY TUMOR: pT2: Tumor which is: >3cm OR invades visceral pleura

REGIONAL LYMPH NODES: pN1: Metastasis in ipsilateral peribronchial, hilar, or intrapulmonary nodes, including those involved by direct extension.

. MARGINS:

Margins uninvolved by invasive carcinoma.

. VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Absent.

. LYMPHATIC (SMALL VESSEL) INVASION:

Present.

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[REDACTED]

[page 2 of 2]
SP-CONS - SURG PATH REPORT -

ADDITIONAL PATHOLOGIC FINDINGS:

Other: Focal, small non-caseating granulomas in uninvolved lung, fungal (GMS) and acid fast bacteria (AFB) stains are negative.

NOTE: This case was presented at the daily quality assurance conference. EGFR and KRAS mutation analysis has been ordered and will be reported in an addendum.

3. STATION 6 LYMPH NODES (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

4. STATION 5 LYMPH NODE (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

5. STATION 7 LYMPH NODE (EXCISION): ONE LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

ADDENDUM ----- Pathologist:

KRAS MUTATION ANALYSIS:

BLOCK TESTED:

RESULT: NO MUTATION DETECTED

NOTE: No mutations were detected at codons 12 and 13 of the KRAS gene.

A copy of the complete report is available in and is also on file in the Molecular Pathology Division of the Department.

ADDENDUM ----- Pathologist:

EGFR MUTATION ANALYSIS:

BLOCK TESTED:

RESULT: NO MUTATION DETECTED

NOTE: A copy of the complete report is available in and is also on file in the Molecular Pathology Division of the Department.

***** End of Diagnosis *****

Clinical History:

LEFT UPPER LOBE OF LUNG

See for official report.

Reported by:

Source: NCI Genomic Data Commons file e3114458-4138-44da-8629-37ab444658b5 (TCGA-49-6742.D9853B55-FD00-4A20-8181-5F4DAD297724.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).